Gene-level copy-number profile of tumor specimen TCGA-2H-A9GQ-01A from TCGA case TCGA-2H-A9GQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 80.8 years (29,497 days).
Specimen TCGA-2H-A9GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.1d7bfec9-5e53-44da-a74a-fc5131a64aa2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GQ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43c0f0cf-be42-4f64-9f1d-50ae9a288713

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 3,414; copy number 2: 19,832; copy number 3: 27,112; copy number 4: 6,106; copy number 5: 1,927; copy number 6: 783; copy number 7: 373; copy number 8: 162; copy number 10: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GQ-01A-11D-A37B-01): tumor purity 0.85, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,185,020–76,399,490, 1 gene (within-gene range 0–2): AC073091.1.
- chr2:76,258,034–76,445,410, 3 genes: PNPP1, USP21P2, RN7SKP203.
- chr2:138,278,574–138,501,698, 6 genes: RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2.
- chr3:4,414,580–4,414,960, 1 gene: MRPS10P2.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:116,360,024–116,646,727, 4 genes: LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2.
- chr3:116,965,112–116,965,227, 1 gene: RNU5E-8P.
- chr4:39,133,913–39,285,810, 2 genes (within-gene range 0–2): AC079921.2, WDR19.
- chr4:90,370,123–90,370,427, 1 gene: RN7SKP248.
- chr5:60,021,249–60,548,813, 8 genes: AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr5:60,630,514–60,630,973, 1 gene: CAB39P1.
- chr5:61,332,258–61,546,172, 4 genes (within-gene range 0–1): ZSWIM6, AC122718.2, AC122718.1, RPL3P6.
- chr6:143,327,275–143,327,655, 1 gene: AL136116.1.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr12:1,380,060–1,391,502, 2 genes: AC004672.1, AC004672.2.
- chr12:112,256,800–112,267,394, 2 genes: AC004217.1, RN7SKP71.
- chr14:50,326,526–50,327,909, 1 gene (within-gene range 0–1): AL359397.2.
- chr15:67,521,131–67,807,117, 4 genes (within-gene range 0–3): C15orf61, AC016355.1, MAP2K5, HNRNPA1P5.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.
- chr17:4,004,445–4,143,030, 1 gene (within-gene range 0–2): ZZEF1.
- chr17:4,143,168–4,187,310, 1 gene: CYB5D2.
- chr17:4,163,910–4,186,424, 2 genes: AC087292.1, Y_RNA.
- chr20:14,884,250–15,280,873, 5 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 563 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,995,211–161,766,227, 57 genes, copy number 8: F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1.
- chr3:162,486,541–173,336,965, 140 genes, copy number 7–10 (broad region; genes not listed).
- chr3:173,644,231–173,644,711, 1 gene, copy number 7: AC092967.1.
- chr8:61,714,788–69,834,978, 116 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:82,862,779–85,977,154, 46 genes, copy number 7: AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2.
- chr8:86,016,819–86,017,126, 1 gene, copy number 7: AC023194.1.
- chr8:106,215,763–118,622,112, 95 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:123,497,889–129,730,445, 97 genes, copy number 7 (broad region; genes not listed).
- chr21:31,559,245–31,840,858, 10 genes, copy number 7: AP000251.1, FBXW11P1, AP000253.1, SOD1, AP000254.1, AP000254.2, SCAF4, HMGN1P2, AP000255.1, TPT1P1.

Autosomal genes at a single copy (total copy number 1): 1,080. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
